Gene-level copy-number profile of tumor specimen HCM-BROD-0098-C15-06A from HCMI case HCM-BROD-0098-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 77.3 years (28,226 days).
Specimen HCM-BROD-0098-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 49f5ce6d-f3b4-4515-949c-b6616fd654b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0098-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/0468f038-63c5-4669-ad8d-7c1b2a67fa92

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 300; copy number 1: 1,560; copy number 2: 25,255; copy number 3: 14,102; copy number 4: 12,640; copy number 5: 3,618; copy number 6: 564; copy number 7: 647; copy number 8: 118; copy number 9: 10; copy number 10: 23; copy number 11: 17; copy number 12: 2; copy number 14: 8; copy number 16: 17.

Homozygous deletions (total copy number 0; autosomes only): 84 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:3,041,422–3,243,960, 1 gene (within-gene range 0–2): HTT.
- chr4:8,981,436–8,990,806, 2 genes: AC073648.3, AC073648.2.
- chr8:8,027,077–8,040,953, 2 genes: FAM90A12P, OR7E96P.
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–4): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–2): RN7SL5P.
- chr10:79,825,902–79,827,602, 1 gene (within-gene range 0–1): AL135925.1.
- chr11:1,012,823–1,201,138, 4 genes: MUC6, LINC02688, MUC2, MUC5AC.
- chr11:64,103,188–64,119,210, 2 genes (within-gene range 0–2): FLRT1, AP006333.1.
- chr11:119,289,562–121,113,108, 40 genes (within-gene range 0–2): RNU6-262P, MCAM, MIR6756, AP002956.1, RNF26, AP003396.1, C1QTNF5, MFRP, USP2, USP2-AS1, AP003396.3, AP003396.2, AP003396.4, THY1, THY1-AS1, DUXAP5, KRT8P7, AP003393.1, NECTIN1, RNU6-1123P, NECTIN1-AS1, AP003390.1, AP001994.1, AP001360.3, LINC02744, AP001360.1, TRIM29, AP000679.1, OAF, POU2F3, AP001150.1, TLCD5, ARHGEF12, 7SK, GRIK4, ELOCP22, AP004147.1, HMGB1P42, TBCEL, TBCEL-TECTA.
- chr11:131,004,128–132,336,822, 14 genes (within-gene range 0–2): RN7SL167P, AP002856.3, AP002856.1, AP002856.4, AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT.
- chr12:95,076,749–95,217,482, 3 genes: FGD6, AC126615.2, AC126615.1.
- chr12:108,129,288–108,339,317, 3 genes (within-gene range 0–2): WSCD2, AC009729.1, CMKLR1.
- chr17:58,218,548–58,268,518, 3 genes (within-gene range 0–2): LPO, AC005962.2, AC004687.3.
- chr20:14,554,384–14,758,056, 2 genes (within-gene range 0–2): MACROD2-IT1, RPS10P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,024 genes in 65 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,632,163–1,745,992, 10 genes, copy number 6: MMP23B, CDK11B, FO704657.1, SLC35E2B, AL691432.1, MMP23A, CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:7,784,320–13,825,079, 207 genes, copy number 5 (broad region; genes not listed).
- chr1:15,111,815–19,210,266, 131 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:29,192,774–30,361,010, 14 genes, copy number 5: ALK, AC074096.1, RN7SL516P, AC106870.3, AC106870.2, AC106870.1, AC016907.2, AC016907.1, YPEL5, SNORA10B, H3P5, LBH, AC109642.1, LINC01936.
- chr2:47,192,405–47,387,601, 7 genes, copy number 7 (within-gene range 4–7): EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP.
- chr2:84,821,650–86,213,790, 58 genes, copy number 6–8: TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1, POLR1A, PTCD3, SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35.
- chr2:159,768,628–166,611,482, 78 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:177,264,359–177,392,691, 8 genes, copy number 5 (within-gene range 3–5): AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2.
- chr2:181,076,051–197,786,762, 192 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr3:142,580,910–142,723,881, 6 genes, copy number 6: RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1.
- chr3:196,291,219–198,123,232, 70 genes, copy number 5 (broad region; genes not listed).
- chr4:190,064,502–190,092,279, 10 genes, copy number 5: DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:21,750,673–24,271,863, 21 genes, copy number 5–6 (within-gene range 3–6): CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1.
- chr5:41,730,065–55,066,230, 136 genes, copy number 5 (broad region; genes not listed).
- chr5:119,445,716–119,681,080, 7 genes, copy number 7: RNA5SP190, HSD17B4, AC010409.1, FABP5P6, FAM170A, TUBAP15, AC008550.1.
- chr5:132,747,426–132,875,046, 9 genes, copy number 6: CCNI2, SEPTIN8, SOWAHA, AC004775.1, SHROOM1, RNA5SP192, GDF9, UQCRQ, LEAP2.
- chr5:147,870,682–148,442,836, 19 genes, copy number 5: SCGB3A2, C5orf46, AC011352.1, AC011352.3, EEF1GP2, SPINK5, AC011346.1, SPINK14, SPINK6, HMGN1P16, MARCOL, SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1.
- chr6:25,782,915–34,576,656, 592 genes, copy number 5–10 (broad region; genes not listed).
- chr6:36,127,809–38,640,148, 56 genes, copy number 5 (within-gene range 3–5): MAPK13, Z84485.1, BRPF3, PNPLA1, BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1, BTBD9, AL033518.1, BTBD9-AS1.
- chr6:170,535,120–170,738,536, 8 genes, copy number 5: PSMB1, TBP, PDCD2, AL672310.1, OR4F7P, WBP1LP8, AL731661.1, AL731684.1.
- chr8:7,200,756–7,298,024, 9 genes, copy number 6: AF228730.1, AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P.
- chr8:99,873,200–143,878,467, 612 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:61,190,003–61,662,690, 11 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:120,851,305–123,171,875, 44 genes, copy number 5–6 (within-gene range 3–6): WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2, BTBD16, RNU6-728P, PLEKHA1, MIR3941, BX842242.1, ARMS2, HTRA1, DMBT1, C10orf120, DMBT1L1, CUZD1, AC073585.1, FAM24B, C10orf88B, FAM24A, C10orf88, PSTK, IKZF5, ACADSB, HMX3, HMX2, BUB3, RPS26P39.
- chr10:125,574,371–126,009,592, 18 genes, copy number 6 (within-gene range 3–6): TEX36-AS1, TEX36, ALDOAP2, AL158835.1, EDRF1-DT, AL158835.3, AL158835.2, EDRF1, EDRF1-AS1, MMP21, UROS, MIR4484, BCCIP, DHX32, Metazoa_SRP, RNU2-42P, FANK1, GNG10P1.
- chr11:57,233,577–57,381,150, 6 genes, copy number 7: APLNR, TNKS1BP1, AP000781.1, SSRP1, P2RX3, PRG3.
- chr11:69,103,493–72,239,147, 102 genes, copy number 8–16 (within-gene range 4–16) (broad region; genes not listed).
- chr11:78,015,715–79,441,030, 23 genes, copy number 8–11 (within-gene range 4–11): AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1.
- chr12:54,292,111–54,497,688, 12 genes, copy number 7 (within-gene range 4–7): NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1.
- chr13:73,054,976–73,661,891, 8 genes, copy number 5 (within-gene range 2–5): KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393.
- chr15:45,321,077–100,544,995, 1,314 genes, copy number 5–9 (broad region; genes not listed).
- chr15:101,116,603–101,979,093, 38 genes, copy number 5–7: AC019254.2, AC019254.1, CHSY1, SELENOS, SNRPA1, PCSK6, AC023024.1, AC023024.2, PCSK6-AS1, AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:46,469,341–48,850,015, 65 genes, copy number 5 (broad region; genes not listed).
- chr16:78,793,584–90,222,851, 320 genes, copy number 5 (broad region; genes not listed).
- chr17:41,730,127–41,851,447, 7 genes, copy number 6: RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1.
- chr19:9,751,993–11,435,782, 97 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:13,731,760–27,646,483, 540 genes, copy number 5–6 (broad region; genes not listed).
- chr19:28,435,388–31,787,255, 56 genes, copy number 5: AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P.
- chr19:33,299,934–34,229,515, 21 genes, copy number 5: AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20, RPS4XP21, CHCHD2P3, LSM14A.
- chr21:45,974,489–46,691,226, 30 genes, copy number 5: AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 901. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
